Somatic mutation profile of tumor specimen TCGA-D8-A145-01A (aliquot TCGA-D8-A145-01A-11D-A10Y-09) from TCGA case TCGA-D8-A145, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.2 years (29,280 days).
Specimen TCGA-D8-A145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af1f984-6896-4c42-9102-1bb0265d7b41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A145-10A (Blood Derived Normal), aliquot TCGA-D8-A145-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10c7a476-08af-4259-ac8b-fcce01f8198a

The open-access MAF lists 40 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 31, Silent 5, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARNTL | c.1651A>T p.S551C (on ENST00000403290 / NM_001297719.2; = p.S550C on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV99533710; called by muse, mutect2
- ARPC2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1041531687, COSV55284943; called by muse, mutect2, varscan2
- CCND3 | c.314T>A p.V105D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65912683; called by mutect2, varscan2
- CECR2 | c.2467C>T p.R823C (on ENST00000342247 / NM_001290047.2; = p.R640C on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs771332466, COSV52841317; called by muse, mutect2, varscan2
- CEP170 | c.3889del p.A1297Lfs*6 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as COSV60509183; called by mutect2, pindel, varscan2
- CX3CR1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64193927, COSV64194636; called by muse, mutect2, varscan2
- DNAH1 | c.8716G>A p.A2906T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV70229084; called by muse, mutect2, varscan2
- FAM120C | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100070209; called by muse, mutect2
- FMO2 | c.123G>C p.W41C | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947787; called by muse, mutect2, varscan2
- GDAP2 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs780934017, COSV101032071; called by muse, mutect2, varscan2
- KCNJ10 | c.50G>C p.S17T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100927953, COSV63633656; called by muse, mutect2, varscan2
- LAMA3 | c.6700C>A p.Q2234K (on ENST00000313654 / NM_198129.4; = p.Q625K on NM_000227.6) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs774924039, COSV52534796; called by muse, mutect2, varscan2
- LMNTD1 | c.1043T>C p.I348T | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs368068515; called by muse, mutect2, varscan2
- MCC | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV56729032, COSV56729052; called by muse, mutect2, varscan2
- MGAM | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs768055689, COSV101527550; called by muse, mutect2
- MRGPRX1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs752611901, COSV100245786, COSV57107242, COSV57107590; called by muse, mutect2
- NEB | c.12334T>G p.Y4112D | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51417706; called by muse, mutect2, varscan2
- NRROS | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs766225300, COSV60745053; called by mutect2, varscan2
- NTSR1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764154462, COSV65138432; called by muse, mutect2
- NUP155 | c.2018T>A p.I673N (on ENST00000231498 / NM_153485.3; = p.I614N on NM_004298.4) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51530004; called by muse, mutect2, varscan2
- OR8H1 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100477028, COSV57294119; called by muse, mutect2
- PHF8 | c.1249G>A p.G417S (on ENST00000357988 / NM_001184896.1; = p.G381S on NM_015107.3) | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV100154999, COSV57681767, COSV57688145; called by muse, mutect2, varscan2
- PIK3C2B | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV100916162; called by muse, mutect2
- RBFOX1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1360100229, COSV60982546; called by muse, mutect2
- RNF213 | c.1269C>T p.T423= | Splice Region (SNP) | VAF 25/148 reads (17%) | catalogued as rs1475572337, COSV60624122; called by muse, mutect2
- SEMA3D | c.424C>G p.H142D | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99406897; called by muse, mutect2
- SLC52A3 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99448082; called by muse, mutect2
- SRRM2 | c.6050G>A p.R2017H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.902); catalogued as rs141721695; called by muse, mutect2, varscan2
- TNKS | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs762904486, COSV100127316; called by muse, mutect2
- TSHZ2 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.374); catalogued as COSV61588796; called by muse, mutect2, varscan2
- TTI1 | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 36/431 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1358540417, COSV100989657; called by muse, mutect2
- UPP2 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99135030; called by muse, mutect2
- WWC3 | c.143del p.Q48Rfs*46 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as COSV66503446; called by mutect2, pindel, varscan2
- JAK1 | c.1035dup p.L346Tfs*4 | Frame Shift Ins (INS) | VAF 53/303 reads (17%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.2314C>T p.L772= | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as COSV52285886; called by muse, mutect2, varscan2
- BCL2L1 | c.447A>T p.A149= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV56967605, COSV56969995; called by muse, mutect2, varscan2
- MAPK4 | c.1590C>T p.D530= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1234966576, COSV68542229; called by muse, mutect2
- MVK | c.1167C>G p.V389= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV57331898; called by muse, mutect2
- SEC24B | c.3552T>G p.L1184= | Silent (SNP) | VAF 35/293 reads (12%) | catalogued as rs1440119785, COSV54499488; called by muse, mutect2, varscan2
